Gene-level copy-number profile of tumor specimen TCGA-IG-A3QL-01A from TCGA case TCGA-IG-A3QL, project TCGA-ESCA (Esophageal Carcinoma). Sex at birth: male; Vital status: Alive; Primary diagnosis: Squamous cell carcinoma, keratinizing, NOS; Tissue or organ of origin: Lower third of esophagus; AJCC pathologic stage: Stage IIA; Tumor grade: G2; Age at diagnosis: 54.1 years (19,755 days).
Specimen TCGA-IG-A3QL-01A: Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Primary; Preservation method: OCT.
Source: NCI Genomic Data Commons open-access Gene Level Copy Number file TCGA-ESCA.95a0fffb-aee0-4e30-9482-71bb5c01a6c2.ascat3.gene_level_copy_number.v36.tsv, workflow ASCAT3 (allele-specific copy number) on an Affymetrix SNP 6.0 array pair, germline comparator TCGA-IG-A3QL-10A (blood derived normal); Data Release 46.0 - August 10, 2026. Values are absolute (integer) total copy numbers per gene for 60,623 GENCODE v36 genes, of which 809 have no estimate. GDC also holds other gene-level copy-number files for this specimen, not rendered: ASCAT2.
https://portal.gdc.cancer.gov/files/eda4ebdf-52cf-4d31-8dad-5961dac3769b

Most common (modal) total copy number across autosomal genes: 2 — the diploid value.
Genes by total copy number (all chromosomes): copy number 1: 938; copy number 2: 20,492; copy number 3: 18,186; copy number 4: 12,980; copy number 5: 2,627; copy number 6: 4,377; copy number 7: 214.

Homozygous deletions (total copy number 0; autosomes only): none.

Amplified relative to the modal value (total copy number ≥ 5, i.e. more than twice the modal value of 2; autosomes only): 7,218 genes in 8 contiguous regions (coordinates GRCh38, first to last gene; gene names only for focal regions of at most 60 genes; where a gene spans a copy-number breakpoint, the lowest–highest segment value inside the gene is given as 'within-gene range'):
- chr2:116,687,218–122,887,691, 79 genes, copy number 5–6 (broad region; genes not listed).
- chr2:123,421,486–152,877,767, 451 genes, copy number 5–6 (broad region; genes not listed).
- chr2:163,288,995–163,736,012, 2 genes, copy number 6: RNU6-627P, FIGN.
- chr3:90,184,634–180,213,108, 1,385 genes, copy number 5 (broad region; genes not listed).
- chr7:63,011,463–159,233,377, 1,935 genes, copy number 5–7 (broad region; genes not listed).
- chr8:150,584–145,066,685, 2,481 genes, copy number 5–6 (broad region; genes not listed).
- chr12:66,767–34,249,958, 850 genes, copy number 6 (broad region; genes not listed).
- chr17:51,630,313–55,872,939, 35 genes, copy number 5 (within-gene range 4–5): CA10, AC002090.1, LINC01982, LINC02089, LINC02876, MTCO1P40, AC034268.2, AC005341.1, AC090079.1, AC090079.2, AC034268.1, RPS2P48, KIF2B, AC023934.1, ISCA1P3, AC015943.1, AC005951.1, ARL2BPP8, RN7SKP14, TOM1L1, COX11, AC007485.2, AC007485.1, STXBP4, HLF, AC007638.2, AC007638.1, MMD, SMIM36, AC105021.1, GARS1P1, RNU6-1249P, TMEM100, PCTP, AC090618.1.

Autosomal genes at a single copy (total copy number 1): 1. Sex chromosomes are excluded from the deletion and amplification lists above because the expected copy number there depends on sex.
